Gene-level copy-number profile of tumor specimen ALCH-ADMX-TTP1-A from ALCHEMIST case ALCH-ADMX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 47.8 years (17,451 days).
Specimen ALCH-ADMX-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 09ff8af3-908a-40d3-af8b-34b8104bd832.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADMX-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,252 have no estimate.
https://portal.gdc.cancer.gov/files/0d76a678-28ee-4824-8b57-f0ad166bfdd3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 141; copy number 1: 10,094; copy number 2: 44,585; copy number 3: 3,470; copy number 4: 47; copy number 5: 13; copy number 6: 6; copy number 7: 5; copy number 8: 5; copy number 11: 2; copy number 13: 1; copy number 14: 1; copy number 29: 1.

Homozygous deletions (total copy number 0; autosomes only): 93 genes in 45 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:9,651,731–9,729,114, 4 genes (within-gene range 0–2): PIK3CD, PIK3CD-AS1, AL691449.1, PIK3CD-AS2.
- chr1:13,474,973–13,516,270, 2 genes: LRRC38, AL354712.1.
- chr2:38,743,599–38,785,002, 4 genes: SRSF7, GEMIN6, TTC39DP, NPLP1.
- chr2:73,202,574–73,212,513, 1 gene: NOTO.
- chr2:85,657,314–85,668,741, 1 gene: SFTPB.
- chr2:89,906,757–89,916,052, 2 genes: IGKV3D-34, IGKV1D-33.
- chr2:90,114,838–90,115,402, 1 gene (within-gene range 0–1): IGKV3D-15.
- chr2:90,309,230–90,315,836, 2 genes: AC233263.2, IGKV1OR2-118.
- chr2:91,578,478–91,580,863, 2 genes: AC233266.1, AC233266.2.
- chr2:200,780,495–200,849,144, 5 genes (within-gene range 0–2): BZW1-AS1, BZW1, RNU6-31P, BICD1P1, RNA5SP115.
- chr2:231,713,314–231,713,398, 1 gene: MIR1244-1.
- chr3:49,108,046–49,120,938, 1 gene: USP19.
- chr3:49,162,535–49,176,486, 2 genes: CCDC71, KLHDC8B.
- chr3:49,467,115–49,467,228, 1 gene: RNA5SP130.
- chr3:50,419,781–50,419,899, 1 gene (within-gene range 0–1): RNA5SP131.
- chr4:49,523,648–49,523,857, 1 gene: AC119751.2.
- chr6:73,368,555–73,395,133, 4 genes (within-gene range 0–1): OOEP, OOEP-AS1, RPL39P3, RPS6P8.
- chr7:5,495,819–5,495,917, 1 gene (within-gene range 0–2): MIR589.
- chr7:100,673,567–100,694,250, 2 genes: GNB2, GIGYF1.
- chr8:11,576,257–11,582,817, 1 gene: LINC00208.
- chr9:63,728,877–63,762,824, 3 genes (within-gene range 0–1): AL772155.1, AL772155.2, MYO5BP3.
- chr9:67,697,076–67,726,255, 5 genes: Y_RNA, FAM27E3, AL627230.3, FAM27B, AL627230.1.
- chr10:101,131,300–101,137,789, 1 gene: TLX1.
- chr10:103,608,619–103,610,050, 1 gene (within-gene range 0–2): AL121929.2.
- chr11:70,603,304–70,604,859, 1 gene (within-gene range 0–2): AP001271.2.
- chr12:121,856,259–121,857,059, 1 gene (within-gene range 0–1): AC079360.1.
- chr14:18,333,726–18,341,859, 1 gene: CR383658.1.
- chr14:18,418,775–18,419,273, 1 gene: BNIP3P6.
- chr14:18,667,249–18,667,370, 1 gene: CR383656.3.
- chr14:105,672,308–105,673,314, 1 gene (within-gene range 0–2): ELK2AP.
- chr17:2,712,309–2,712,833, 1 gene (within-gene range 0–1): AC005696.1.
- chr17:3,601,761–3,602,272, 1 gene (within-gene range 0–1): AC027796.1.
- chr17:3,636,459–3,663,103, 2 genes (within-gene range 0–1): CTNS, AC027796.4.
- chr17:16,342,534–16,391,882, 4 genes (within-gene range 0–2): CENPV, UBB, AC093484.3, FTLP12.
- chr19:1,392,170–1,396,467, 1 gene (within-gene range 0–3): AC005329.1.
- chr20:3,888,239–3,929,882, 5 genes (within-gene range 0–6): PANK2-AS1, PANK2, MIR103A2, MIR103B2, AL031670.1.
- chr20:4,120,980–4,187,747, 1 gene: SMOX.
- chr20:62,633,681–62,635,862, 2 genes: AL450469.2, AL450469.1.
- chr21:8,603,547–9,129,752, 15 genes: RPSAP68, CR381572.1, LINC01666, CR381670.2, SNX18P10, MTCO1P1, CR381670.1, MIR3648-2, CR392039.1, CR392039.3, CDRT15P9, CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2.
- chr22:18,004,270–18,007,308, 1 gene (within-gene range 0–1): AC016027.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 34 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:242,175,181–242,175,634, 1 gene, copy number 8: RPL23AP88.
- chr8:141,968,091–141,968,841, 1 gene, copy number 5: AC104417.1.
- chr8:143,716,340–143,722,458, 1 gene, copy number 7 (within-gene range 0–7): MAPK15.
- chr8:143,977,153–144,047,114, 3 genes, copy number 5–6 (within-gene range 5–8): PARP10, GRINA, SPATC1.
- chr8:144,051,266–144,063,965, 2 genes, copy number 11 (within-gene range 4–11): OPLAH, MIR6846.
- chr9:136,712,572–136,726,239, 3 genes, copy number 7–8: DIPK1B, SNORA17B, SNORA17B.
- chr9:136,738,167–136,748,525, 3 genes, copy number 6 (within-gene range 2–6): AL355987.1, LCN6, MIR6722.
- chr10:44,712–46,884, 1 gene, copy number 29: AL713922.1.
- chr11:2,163,929–2,173,138, 2 genes, copy number 8: TH, MIR4686.
- chr12:132,186,735–132,189,695, 1 gene, copy number 5: LINC02361.
- chr14:105,620,506–105,626,066, 2 genes, copy number 13–14: IGHG4, MIR8071-1.
- chr16:817,489–981,318, 3 genes, copy number 5 (within-gene range 1–6): AL023882.1, AL031008.1, LMF1.
- chr16:921,033–1,000,926, 5 genes, copy number 5 (within-gene range 5–6): LMF1-AS1, AC009041.3, CEROX1, SOX8, AC009041.1.
- chr16:88,651,935–88,663,161, 1 gene, copy number 7: MVD.
- chr19:1,065,923–1,095,380, 2 genes, copy number 5: ARHGAP45, POLR2E.
- chr19:1,397,026–1,401,570, 1 gene, copy number 7: GAMT.
- chr20:63,166,797–63,180,903, 1 gene, copy number 7 (within-gene range 3–7): AL096828.1.
- chr20:63,528,001–63,537,376, 1 gene, copy number 6: PTK6.

Autosomal genes at a single copy (total copy number 1): 10,093. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
